Gene-level copy-number profile of tumor specimen TCGA-IN-A6RR-01A from TCGA case TCGA-IN-A6RR, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 84.1 years (30,734 days).
Specimen TCGA-IN-A6RR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.fc6baf1e-d0d0-4200-98cc-91e32122cac2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-A6RR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fdfb39e8-dbcd-485d-8357-2eea6ec4568c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 17,471; copy number 2: 38,568; copy number 3: 3,237; copy number 4: 345; copy number 5: 84; copy number 6: 6; copy number 7: 21; copy number 8: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-A6RR-01A-12D-A32M-01): tumor purity 0.79, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,090,898–9,442,380, 2 genes: RPS26P3, RN7SL5P.
- chr10:86,889,569–87,841,343, 39 genes (within-gene range 0–1): RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 158 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,721,167–70,686,816, 25 genes, copy number 5 (within-gene range 3–5): SULT1B1, SULT1D1P, AC108941.3, SULT1E1, AC108941.1, CSN1S1, CSN2, STATH, HTN3, HTN1, CSN1S2AP, PRR27, ODAM, FDCSP, CSN3, CABS1, SMR3A, SMR3B, OPRPN, MUC7, AMTN, AMBN, ENAM, AC009570.2, JCHAIN.
- chr7:53,187,388–55,862,755, 53 genes, copy number 6–8 (within-gene range 2–8): HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr17:39,461,486–40,061,215, 29 genes, copy number 5 (within-gene range 2–5): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124.
- chr18:20,946,906–23,260,467, 51 genes, copy number 5–7 (within-gene range 4–7): ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1.

Autosomal genes at a single copy (total copy number 1): 15,091. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
